Gene-level copy-number profile of tumor specimen TCGA-AA-A00O-01A from TCGA case TCGA-AA-A00O, project TCGA-COAD (Colon Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Sigmoid colon; AJCC pathologic stage: Stage IIIC; Age at diagnosis: 83.0 years (30,316 days).
Specimen TCGA-AA-A00O-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-COAD.247793cb-05d0-45f3-8652-4f8a6c8a6954.gene_level_copy_number.v36.tsv, workflow ASCAT2 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-AA-A00O-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 362 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/b427ed32-ccf5-4600-9c92-806322d0d6a0

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 524; copy number 1: 8,924; copy number 2: 38,178; copy number 3: 10,894; copy number 4: 519; copy number 5: 35; copy number 6: 571; copy number 7: 456; copy number 8: 97; copy number 10: 63.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-AA-A00O-01A-02D-A008-01): tumor purity 0.61, ploidy 1.96, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 3 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr8:39,314,591–39,580,134, 3 genes (within-gene range 0–2): ADAM5, ADAM3A, AC123767.1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 1,222 genes in 10 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:88,811,186–88,861,563, 1 gene, copy number 8 (within-gene range 3–8): AC244205.1.
- chr2:88,857,161–89,117,844, 24 genes, copy number 8: IGKC, IGKJ5, IGKJ4, IGKJ3, IGKJ2, IGKJ1, IGKV4-1, IGKV5-2, IGKV7-3, PGBD4P5, IGKV2-4, IGKV1-5, IGKV1-6, IGKV3-7, IGKV1-8, IGKV1-9, IGKV2-10, IGKV3-11, IGKV1-12, IGKV1-13, IGKV2-14, IGKV3-15, IGKV1-16, IGKV1-17.
- chr6:39,792,298–44,527,448, 162 genes, copy number 5–10 (broad region; genes not listed).
- chr6:44,727,921–45,377,953, 7 genes, copy number 5: AL133334.1, SUPT3H, NUDT19P4, AL138880.2, RBM22P4, AL138880.1, MIR586.
- chr13:19,026,001–19,032,626, 2 genes, copy number 5: GTF2IP3, AL137001.1.
- chr16:5,596,856–6,092,954, 5 genes, copy number 5: LINC01570, MIR8065, AC012175.1, AC009135.2, AC009135.1.
- chr20:1,516,759–5,316,954, 121 genes, copy number 6 (within-gene range 1–6) (broad region; genes not listed).
- chr20:5,346,006–5,346,160, 1 gene, copy number 6: RNA5-8SP7.
- chr20:6,446,723–6,528,459, 1 gene, copy number 6: CASC20.
- chr20:30,278,906–64,313,132, 898 genes, copy number 5–7 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 8,920. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
